Somatic mutation profile of tumor specimen TARGET-40-NAAGKL-01A (aliquot TARGET-40-NAAGKL-01A-01D) from TARGET case TARGET-40-NAAGKL, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.5 years (6,012 days).
Specimen TARGET-40-NAAGKL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06b2de04-134c-4dc2-83af-f30a023f0a64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGKL-10B (Blood Derived Normal), aliquot TARGET-40-NAAGKL-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acc5bd36-4754-4d16-92c4-445b4034d92d

The open-access MAF lists 64 somatic variants for this specimen: 46 protein-altering or splice-affecting, 8 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 8, Intron 5, 3'UTR 2, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1, 5'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.5986G>A p.G1996R | Missense Mutation (SNP) | VAF 73/364 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs377010256; called by muse, mutect2, varscan2
- ASTN1 | c.3802C>T p.L1268F | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV62491136; called by muse, mutect2, varscan2
- BRWD3 | c.1085C>A p.T362K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV64745574; called by muse, mutect2
- CCS | c.250+1G>A p.X84_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as rs746825506, COSV100039741; called by muse, mutect2, varscan2
- CEP295 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs776939244; called by muse, mutect2, varscan2
- DISC1 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs749280796; called by muse, varscan2
- EPB41L4B | c.518G>C p.R173P | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65799236; called by muse, mutect2, varscan2
- FRMPD3 | c.2766G>C p.K922N | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.16); catalogued as COSV99346716; called by muse, mutect2, varscan2
- KAT6A | c.2806C>A p.P936T | Missense Mutation (SNP) | VAF 90/396 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs367785766; called by muse, mutect2, varscan2
- NUTM2F | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769950535; called by muse, mutect2, varscan2
- PPP4R1 | c.2510A>G p.K837R (on ENST00000400556 / NM_001042388.3; = p.K820R on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs370182987, COSV53284206; called by muse, mutect2, varscan2
- RIN3 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs752099390; called by muse, mutect2, varscan2
- RORB | c.514G>A p.G172S (on ENST00000396204 / NM_001365023.1; = p.G161S on NM_006914.4) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs763192623, COSV65336549; called by muse, mutect2, varscan2
- RYR1 | c.3071G>A p.R1024H | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs148146893; called by muse, mutect2, varscan2
- SLC25A24 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as COSV51448713; called by muse, mutect2, varscan2
- TRBV28 | c.80C>G p.S27W | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs745393218; called by muse, mutect2, varscan2
- UBE3C | c.518A>C p.E173A | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1387383936; called by muse, mutect2, varscan2
- UNC13C | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs746269797, COSV52862396; called by muse, mutect2, varscan2
- UNC5C | c.2671G>T p.V891L | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV71657932, COSV71658965; called by muse, mutect2, varscan2
- ABCB1 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- ABCB1 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADGRV1 | c.7243A>C p.I2415L | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMC4 | c.2108T>G p.F703C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- C9orf131 | c.3025C>T p.L1009F | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CPNE8 | c.1612T>C p.Y538H | Missense Mutation (SNP) | VAF 104/175 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CTBP1 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CTTN | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- DAGLA | c.2021_2027del p.L674Qfs*6 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- DISC1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 74/335 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DISC1 | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HUWE1 | c.6929A>G p.Q2310R | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIN28A | c.139T>C p.F47L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MCU | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- OR10G8 | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- P2RY12 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.216); called by mutect2, varscan2
- PCLO | c.10040G>C p.S3347T | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEG | c.979C>A p.Q327K | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, varscan2
- RBAK | c.1172A>G p.H391R | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RFX4 | c.1726A>G p.R576G (on ENST00000392842 / NM_213594.3; = p.R482G on NM_032491.6) | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RYR2 | c.11445A>C p.E3815D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- SIPA1L1 | c.5289_5311del p.H1764Pfs*60 | Frame Shift Del (DEL) | VAF 37/61 reads (61%) | called by mutect2, pindel, varscan2
- SLC16A3 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYT17 | c.86A>T p.H29L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TYRP1 | c.534A>T p.Q178H | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- UBE3A | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF211 | c.701G>C p.C234S (on ENST00000347302 / NM_198855.4; = p.C247S on NM_006385.5) | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DNAH9 | c.5976T>G p.P1992= | Silent (SNP) | VAF 16/58 reads (28%) | called by mutect2, varscan2
- KLHDC9 | c.276C>T p.L92= | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- LRRC31 | c.129T>C p.D43= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs1482286439; called by muse, mutect2, varscan2
- MUC16 | c.37941C>A p.G12647= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs75995954, COSV67470890, COSV67493606; called by muse, mutect2, varscan2
- NCLN | c.537C>T p.A179= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs1468517165; called by muse, mutect2, varscan2
- OTOF | c.4581C>T p.R1527= (on ENST00000272371 / NM_194248.3; = p.R760= on NM_004802.4) | Silent (SNP) | VAF 92/346 reads (27%) | catalogued as rs560125081; called by muse, mutect2, varscan2
- PARP14 | c.1971C>G p.T657= | Silent (SNP) | VAF 29/236 reads (12%) | called by muse, mutect2, varscan2
- SCN3A | c.5265C>A p.I1755= | Silent (SNP) | VAF 69/186 reads (37%) | catalogued as COSV51802015; called by muse, mutect2, varscan2
- ACAD10 | c.*177A>G | 3'UTR (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- CARS2 | c.1417-191G>A | Intron (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- CYP11B1 | c.*37A>G | 3'UTR (SNP) | VAF 42/292 reads (14%) | called by muse, mutect2, varscan2
- MECR | c.756+452G>A | Intron (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- MT1G | c.-6G>A | 5'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604811 G>A | 5'Flank (SNP) | VAF 49/181 reads (27%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-66725G>A | Intron (SNP) | VAF 54/136 reads (40%) | catalogued as rs776612130; called by muse, mutect2, varscan2
- PKHD1 | c.10156+22426T>G | Intron (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- TTC3P1 | n.5603A>T | RNA (SNP) | VAF 88/262 reads (34%) | called by muse, mutect2, varscan2
- ZNF674 | c.253+5174T>G | Intron (SNP) | VAF 11/40 reads (28%) | catalogued as rs1476789510; called by muse, mutect2, varscan2
